Gene-level copy-number profile of tumor specimen TCGA-CD-A48A-01A from TCGA case TCGA-CD-A48A, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 57.1 years (20,839 days).
Specimen TCGA-CD-A48A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.e880b86a-a1d1-41d9-842f-34605515b0c8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CD-A48A-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c040f3fa-4c73-4c50-8e06-61d9a5bc1c7e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 456; copy number 1: 144; copy number 2: 3,437; copy number 3: 10,860; copy number 4: 16,688; copy number 5: 12,348; copy number 6: 8,193; copy number 7: 3,852; copy number 8: 2,059; copy number 9: 497; copy number 10: 508; copy number 11: 596; copy number 23: 8; copy number 25: 1; copy number 27: 82; copy number 33: 44; copy number 45: 42; copy number 51: 2; copy number 54: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-CD-A48A-01): tumor purity 0.64, ploidy 4.43, whole-genome doublings 2 (call status: snp_call).

Homozygous deletions (total copy number 0; autosomes only): 423 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:21,932,662–22,548,800, 6 genes (within-gene range 0–4): AC096570.1, AC068044.1, AC099799.1, RNA5SP87, LINC01830, LINC01884.
- chr2:55,952,158–56,181,652, 1 gene (within-gene range 0–4): AC011306.1.
- chr2:56,077,417–56,750,563, 6 genes: LINC01813, AC007744.1, AC007743.1, CCDC85A, RNA5SP93, PPIAP63.
- chr2:57,544,535–57,544,599, 1 gene: AC073875.1.
- chr2:77,652,025–81,666,728, 35 genes: AC012494.1, AC084149.1, RPL38P2, LINC01851, AC012494.2, CYCSP6, AC064872.1, AC092660.1, AC092604.1, RNU6-827P, RNU6-812P, REG3G, REG1B, REG1A, REG1CP, REG3A, AC011754.1, CTNNA2, AC011754.2, CTNNA2-AS1, AC010975.1, GNA13P1, RNU6-561P, MIR4264, MIR8080, AC016716.1, RBM7P1, LRRTM1, AC008067.1, AC012355.1, ANKRD11P1, CHMP4AP1, LINC01815, RNA5SP99, AC013262.1.
- chr2:134,455,759–134,719,000, 1 gene (within-gene range 0–3): TMEM163.
- chr4:13,654,374–15,427,914, 16 genes (within-gene range 0–3): LINC01182, AC007126.1, AC095052.1, LINC01085, AC073848.1, AC092546.1, AC006296.3, AC006296.2, AC006296.1, LINC00504, MTND2P31, SNORA63, CPEB2-DT, CPEB2, C1QTNF7-AS1, RN7SKP170.
- chr4:156,634,494–156,692,636, 3 genes: LINC02272, AC096736.2, AC096736.1.
- chr4:171,812,254–173,041,559, 2 genes (within-gene range 0–3): GALNTL6, AC108064.1.
- chr4:180,731,164–181,700,142, 7 genes (within-gene range 0–3): AC104803.1, LINC00290, AC019235.1, LINC02500, AC093840.1, AC093840.2, AC084741.1.
- chr6:65,788,417–67,210,480, 6 genes: SLC25A51P1, ADH5P4, NUFIP1P1, AL450336.1, RNU7-66P, AL591004.1.
- chr8:5,848,697–5,911,236, 3 genes: AC087369.1, AC087369.2, RN7SKP159.
- chr8:46,028,804–46,550,802, 2 genes: AC118650.1, HSPA8P13.
- chr8:64,373,151–64,798,737, 8 genes (within-gene range 0–4): MIR124-2HG, MIR124-2, AC012535.1, AC090136.1, AC090136.2, AC090136.3, BHLHE22, CYP7B1.
- chr9:19,789,179–24,088,051, 86 genes (within-gene range 0–2) (broad region; genes not listed).
- chr11:102,229,851–102,230,922, 1 gene: AP000942.2.
- chr12:76,025,447–76,559,809, 12 genes (within-gene range 0–6): PHLDA1, AC011611.3, AC011611.4, NAP1L1, AC011611.5, AC233290.2, AC233290.1, RNU6-1271P, LNCOG, RN7SKP172, BBS10, OSBPL8.
- chr16:31,259,967–31,952,473, 43 genes (within-gene range 0–4): ITGAM, ITGAX, AC093520.2, ITGAD, AC093520.1, COX6A2, AC026471.5, ZNF843, AC026471.4, AC026471.1, ARMC5, AC026471.6, TGFB1I1, SLC5A2, AC026471.3, RUSF1, AC026471.2, AHSP, LINC02190, AC106730.1, VN1R64P, VN1R65P, FRG2KP, AC106730.2, YBX3P1, ZNF720P1, VN1R66P, RBM22P12, AC074050.1, AC074050.2, CLUHP3, AC074050.4, AC074050.3, ZNF720, AC002519.1, VN1R67P, AC002519.2, VN1R3, RBM22P13, AC034105.2, ZNF267, AC034105.3, AC034105.5.
- chr17:6,322,413–6,556,555, 6 genes (within-gene range 0–2): BTF3P14, AC055872.2, AIPL1, AC055872.1, PIMREG, PITPNM3.
- chr17:20,868,433–21,002,276, 1 gene (within-gene range 0–2): CCDC144NL-AS1.
- chr17:20,938,023–22,205,154, 36 genes (within-gene range 0–4): AC090774.1, SPECC1P2, AC107926.1, AC087393.3, AC087393.1, USP22, AC087393.2, LINC01563, DHRS7B, TMEM11, AC087294.1, RN7SL426P, NATD1, EIF1P5, MAP2K3, KCNJ12, LINC02693, AC068418.3, PDLIM1P2, AC068418.2, AC068418.1, RPL21P120, AC233702.5, AC233702.7, AC233702.8, AC233702.6, AC233702.3, AC233702.2, AC233702.1, AC233702.4, AC233702.9, KCNJ18, AC243725.1, ABBA01006766.1, NCOR1P2, UBBP4.
- chr18:50,795,120–51,283,896, 11 genes: MRO, HNRNPA3P16, RPL17P46, ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P.
- chr19:15,564,074–15,614,553, 4 genes: CYP4F23P, AD000091.1, RPL23AP2, AC093072.1.
- chr21:13,968,489–22,884,000, 119 genes (broad region; genes not listed).
- chr21:27,358,885–27,751,233, 7 genes: AP001605.1, AP001604.1, EIF4A1P1, RPL10P1, NCSTNP1, LINC01673, LINC00113.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,782 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:60,336,446–67,825,562, 162 genes, copy number 10 (broad region; genes not listed).
- chr2:82,268,427–84,966,685, 29 genes, copy number 11 (within-gene range 6–11): LYARP1, RNU6-685P, Y_RNA, AC010105.1, RBX1P1, MTND4P25, MTND5P27, MTND6P7, MTCYBP7, AC098817.1, DHFRP3, AC138623.1, LINC01809, RPL37P10, RNU6-1312P, CRLF3P3, ST6GALNAC2P1, FUNDC2P2, AC106874.1, SUCLG1, DNAH6, DUXAP1, LDHAP7, TRABD2A, AC010087.1, RPL12P18, TMSB10, RPS2P17, AC022210.1.
- chr5:58,198–1,523,962, 56 genes, copy number 9: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, AC026748.7, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075.
- chr9:2,421,597–6,197,248, 73 genes, copy number 23–51 (broad region; genes not listed).
- chr9:6,276,640–6,727,438, 16 genes, copy number 27: AL360221.1, SELENOTP1, TPD52L3, UHRF2, AL133480.1, GLDC, RN7SL25P, AL353718.1, RPL23AP57, AL162411.1, RN7SL123P, RPS3AP54, RNF2P1, RPL35AP20, LINC02851, AL354707.1.
- chr9:6,734,598–6,835,577, 3 genes, copy number 27: PRELID3BP11, SNRPEP2, ACTG1P14.
- chr12:18,242,961–18,648,416, 1 gene, copy number 9 (within-gene range 3–9): PIK3C2G.
- chr12:18,424,663–24,949,101, 82 genes, copy number 9–45 (within-gene range 5–45) (broad region; genes not listed).
- chr12:24,902,309–28,581,511, 85 genes, copy number 33–45 (within-gene range 8–45) (broad region; genes not listed).
- chr12:29,500,840–32,993,754, 90 genes, copy number 9–54 (broad region; genes not listed).
- chr12:58,544,124–74,728,851, 272 genes, copy number 9 (broad region; genes not listed).
- chr20:28,563,850–41,712,600, 346 genes, copy number 10 (broad region; genes not listed).
- chr20:42,685,404–64,313,132, 567 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 134. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
